Somatic mutation profile of tumor specimen TCGA-FV-A2QR-01A (aliquot TCGA-FV-A2QR-01A-11D-A20W-10) from TCGA case TCGA-FV-A2QR, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1.
Specimen TCGA-FV-A2QR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96a581fd-2b9c-4be6-bb90-e15962c5a355.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A2QR-11A (Solid Tissue Normal), aliquot TCGA-FV-A2QR-11A-11D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11bb3cf2-790c-4118-9538-573593bd4ca4

The open-access MAF lists 125 somatic variants for this specimen: 94 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 27, Frame Shift Del 4, In Frame Del 4, Nonsense Mutation 3, 5'Flank 3, Splice Site 3, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8177A>G p.Y2726C | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359064; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.4745T>C p.I1582T | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1225720048, COSV67978771; called by muse, mutect2, varscan2
- ALK | c.2758G>T p.G920C | Missense Mutation (SNP) | VAF 150/339 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66557810; called by muse, mutect2, varscan2
- ALPK2 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 114/283 reads (40%) | catalogued as COSV64490346, COSV64493905; called by muse, mutect2, varscan2
- AP3M2 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 121/292 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51527658; called by muse, mutect2, varscan2
- AP3S1 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); catalogued as COSV57473445; called by muse, mutect2, varscan2
- ARHGEF17 | c.5920C>A p.R1974S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55229539; called by muse, mutect2, varscan2
- BANK1 | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59838497; called by muse, mutect2, varscan2
- C16orf78 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV54555053; called by muse, mutect2, varscan2
- CAND1 | c.2960C>T p.T987M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs751453121, COSV73389530; called by muse, mutect2, varscan2
- CD163L1 | c.4292A>T p.N1431I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV58011223; called by muse, mutect2, varscan2
- CEP290 | c.3328G>T p.D1110Y | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV58348892; called by muse, mutect2, varscan2
- CHMP6 | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57326984; called by muse, mutect2, varscan2
- CLPTM1L | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV57989413; called by muse, mutect2, varscan2
- COL27A1 | c.3141+2T>A p.X1047_splice | Splice Site (SNP) | VAF 53/149 reads (36%) | catalogued as COSV61921718; called by muse, mutect2, varscan2
- DRD3 | c.779A>C p.Q260P | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.868); catalogued as COSV55678699, COSV99879500; called by muse, mutect2, varscan2
- DUSP29 | c.17T>A p.V6E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV58300031; called by muse, mutect2, varscan2
- EPHB2 | c.1775G>T p.G592V (on ENST00000400191 / NM_001309193.2; = p.G593V on NM_004442.7) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65860012; called by muse, mutect2, varscan2
- ERG28 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1463985777, COSV53160913; called by muse, mutect2, varscan2
- EVX1 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs994524662, COSV56084783; called by mutect2, varscan2
- FAT2 | c.9889A>G p.S3297G | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55813488, COSV55820167; called by muse, mutect2, varscan2
- FBXO38 | c.2360G>A p.R787K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.163); catalogued as COSV57025879; called by muse, mutect2, varscan2
- FLT4 | c.3807G>T p.V1269= | Splice Region (SNP) | VAF 45/114 reads (39%) | catalogued as COSV56098616; called by muse, mutect2, varscan2
- GALNT6 | c.1813C>A p.P605T | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV62541660; called by muse, mutect2, varscan2
- GIMAP8 | c.931A>G p.N311D | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56229757; called by muse, mutect2, varscan2
- HEATR1 | c.1992G>C p.M664I | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV63979860; called by muse, mutect2
- HELZ | c.4067C>T p.P1356L | Missense Mutation (SNP) | VAF 125/464 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV62376423; called by muse, mutect2, varscan2
- HLA-E | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64927225; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1307C>A p.T436K | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54560219; called by muse, mutect2, varscan2
- HS1BP3 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV58311946; called by muse, mutect2, varscan2
- HYDIN | c.12536C>A p.T4179K | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV101125251; called by muse, varscan2
- HYDIN | c.12535A>G p.T4179A | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV66637260; called by muse, varscan2
- IFI16 | c.605A>T p.K202I | Missense Mutation (SNP) | VAF 111/333 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV55531205; called by muse, mutect2, varscan2
- IFNA6 | c.242A>C p.H81P | Missense Mutation (SNP) | VAF 103/226 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66506173; called by muse, mutect2, varscan2
- IL31RA | c.1557G>T p.K519N | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV51679051; called by muse, mutect2, varscan2
- IRF1 | c.46A>C p.I16L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55376100; called by muse, mutect2, varscan2
- ITGB8 | c.1157C>A p.S386* | Nonsense Mutation (SNP) | VAF 56/149 reads (38%) | catalogued as COSV56005074; called by muse, mutect2, varscan2
- KRT17 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 203/549 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.17); catalogued as COSV60859977; called by muse, mutect2, varscan2
- LACC1 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as rs150202700; called by muse, mutect2, varscan2
- LRP1B | c.1112A>C p.Q371P | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV67187623; called by muse, mutect2, varscan2
- MCL1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.225); catalogued as rs1490867890, COSV57189624, COSV57189738; called by mutect2, varscan2
- MDC1 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV64523337; called by muse, mutect2, varscan2
- MLLT3 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 162/409 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1031452176, COSV63494977; called by muse, mutect2, varscan2
- MORC2 | c.1366A>G p.I456V (on ENST00000397641 / NM_001303256.3; = p.I394V on NM_014941.3) | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1237819801, COSV53196363; called by muse, mutect2, varscan2
- MPEG1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV57088383; called by muse, mutect2, varscan2
- MYLK2 | c.626A>G p.E209G | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV65658553; called by muse, mutect2, varscan2
- MYO10 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV72453876; called by muse, mutect2, varscan2
- NAV3 | c.3727A>G p.I1243V | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.968); catalogued as COSV57062740; called by muse, mutect2, varscan2
- NF1 | c.4110+1G>C p.X1370_splice | Splice Site (SNP) | VAF 26/88 reads (30%) | catalogued as CS000898, CS971829, COSV62193545, COSV62207614; called by muse, mutect2, varscan2
- NFXL1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.499); catalogued as COSV61198041; called by muse, mutect2, varscan2
- NPHS1 | c.380T>A p.V127E | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV62286399; called by muse, mutect2
- OR4S2 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 106/283 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as rs1295933490, COSV56745932; called by muse, mutect2, varscan2
- OR51G1 | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58968482; called by muse, mutect2, varscan2
- P2RY12 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV56368904; called by muse, mutect2, varscan2
- PDE11A | c.2346G>T p.E782D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV53686566, COSV53712120; called by muse, mutect2, varscan2
- PEAR1 | c.1075T>C p.C359R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355647842, COSV52770882; called by muse, mutect2, varscan2
- PLIN2 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1339551820, COSV52802599; called by muse, mutect2, varscan2
- PMS2 | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV56219696; called by muse, mutect2, varscan2
- PPP3CA | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 93/381 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV59919684; called by muse, mutect2, varscan2
- PTGER3 | c.923A>T p.N308I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV60687833; called by muse, mutect2, varscan2
- PTPN22 | c.1208C>T p.P403L (on ENST00000359785 / NM_001193431.2; = p.P348L on NM_012411.5) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV63084353; called by muse, mutect2, varscan2
- RESF1 | c.2636C>T p.S879L | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV57019775; called by muse, mutect2, varscan2
- REV1 | c.1952-1G>A p.X651_splice | Splice Site (SNP) | VAF 45/112 reads (40%) | catalogued as COSV51481902; called by muse, mutect2, varscan2
- RPAP2 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as COSV72509144; called by muse, mutect2, varscan2
- SAMD12 | c.285G>C p.Q95H | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs761510466, COSV59046277; called by muse, mutect2, varscan2
- SEMA3A | c.2163C>A p.F721L | Missense Mutation (SNP) | VAF 111/546 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54862121, COSV54889735; called by muse, mutect2
- SEPTIN4 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as COSV100400483; called by muse, mutect2
- SFPQ | c.1262A>C p.K421T | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV61758258; called by muse, mutect2, varscan2
- SLC10A2 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55357171; called by muse, mutect2, varscan2
- SLC22A11 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs571324325, COSV57251853; called by muse, mutect2, varscan2
- SLC6A13 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58255374; called by muse, mutect2, varscan2
- SLC9A3 | c.1682C>A p.S561Y | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs371187218; called by muse, mutect2, varscan2
- STIL | c.1246A>G p.K416E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV99681408; called by muse, mutect2
- SYNGAP1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs538281267, COSV53378360; called by muse, mutect2, varscan2
- TBK1 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as COSV59153553; called by muse, mutect2, varscan2
- TCTEX1D1 | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV51075087, COSV51075641; called by muse, mutect2, varscan2
- TDRD5 | c.800C>G p.S267* | Nonsense Mutation (SNP) | VAF 39/238 reads (16%) | catalogued as COSV54239067; called by muse, mutect2, varscan2
- TNRC6B | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.358); catalogued as rs367663125, COSV57289322; called by muse, mutect2, varscan2
- TYW1 | c.1852A>T p.M618L | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV62751337; called by muse, mutect2, varscan2
- UVSSA | c.1943G>A p.G648D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV66229292, COSV66229985; called by muse, mutect2, varscan2
- VPS37A | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV61352505; called by muse, mutect2, varscan2
- ZCCHC10 | c.533A>G p.D178G (on ENST00000509437 / NM_001300818.3; = p.D156G on NM_017665.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV60772388; called by muse, mutect2, varscan2
- ZHX2 | c.342A>T p.E114D | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.925); catalogued as COSV58710329; called by muse, mutect2, varscan2
- ZMYM2 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs760872094, COSV67032298; called by muse, mutect2, varscan2
- ZNF208 | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.495); catalogued as rs267605388, COSV101237272, COSV68100730; called by muse, mutect2, varscan2
- ZNF835 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV73379189; called by muse, mutect2, varscan2
- BRCA2 | c.8983_8991del p.D2995_Y2997del | In Frame Del (DEL) | VAF 58/190 reads (31%) | called by mutect2, pindel, varscan2
- KDM4D | c.1556_1570del p.W519_P523del | In Frame Del (DEL) | VAF 42/134 reads (31%) | called by mutect2, pindel, varscan2
- RBM6 | c.2706del p.I902Mfs*69 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- SLC24A4 | c.1433_1439del p.I478Tfs*28 | Frame Shift Del (DEL) | VAF 76/244 reads (31%) | called by mutect2, pindel, varscan2
- SRP72 | c.402_413del p.L135_N138del | In Frame Del (DEL) | VAF 42/135 reads (31%) | called by mutect2, pindel, varscan2
- XRCC6 | c.1582_1597del p.L528Ifs*32 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | called by mutect2, pindel, varscan2
- ZFAT | c.3068_3075del p.A1023Gfs*33 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- ZIC1 | c.617_631del p.A206_A210del | In Frame Del (DEL) | VAF 38/59 reads (64%) | called by mutect2, pindel, varscan2
- ATF7IP2 | c.873G>A p.E291= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV61092228; called by muse, mutect2, varscan2
- C16orf46 | c.871C>T p.L291= | Silent (SNP) | VAF 64/192 reads (33%) | catalogued as COSV55150239; called by muse, mutect2, varscan2
- CCDC9B | c.894A>G p.K298= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as rs143912259; called by muse, mutect2, varscan2
- CD22 | c.1503C>G p.V501= | Silent (SNP) | VAF 55/113 reads (49%) | catalogued as COSV50049646; called by muse, mutect2, varscan2
- CFAP65 | c.2199C>T p.F733= | Silent (SNP) | VAF 80/235 reads (34%) | catalogued as rs1244525585, COSV58558030; called by muse, mutect2, varscan2
- CIT | c.2997G>A p.T999= | Silent (SNP) | VAF 135/390 reads (35%) | catalogued as rs907326946, COSV55860410; called by muse, mutect2, varscan2
- CNTROB | c.945T>C p.A315= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV66607550; called by muse, mutect2
- CXCR5 | c.354G>A p.G118= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as rs1259220217, COSV52682028; called by muse, mutect2, varscan2
- DNAH2 | c.10524T>C p.A3508= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV66716535; called by muse, mutect2, varscan2
- EXTL3 | c.1995G>T p.V665= | Silent (SNP) | VAF 89/155 reads (57%) | catalogued as COSV55036784; called by muse, mutect2, varscan2
- HEY2 | c.666C>T p.H222= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs376521140; called by muse, mutect2, varscan2
- HYDIN | c.12537A>C p.T4179= | Silent (SNP) | VAF 35/171 reads (20%) | catalogued as COSV101125250; called by muse, varscan2
- ITGA2 | c.1395A>T p.I465= | Silent (SNP) | VAF 67/179 reads (37%) | catalogued as COSV56856497; called by muse, mutect2, varscan2
- JMJD4 | c.516C>T p.G172= | Silent (SNP) | VAF 259/416 reads (62%) | catalogued as COSV59916959, COSV59917439; called by mutect2, varscan2
- MITF | c.33C>T p.F11= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV60710747; called by muse, mutect2, varscan2
- NPC1L1 | c.3774G>A p.K1258= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV56922603; called by muse, mutect2, varscan2
- PRRC2C | c.3768C>T p.V1256= (on ENST00000367742; = p.V1254= on NM_015172.4) | Silent (SNP) | VAF 28/421 reads (7%) | catalogued as COSV58901206; called by muse, mutect2
- SCAMP5 | c.336C>T p.F112= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as COSV62642945; called by muse, mutect2, varscan2
- SETD9 | c.93C>T p.N31= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV53649788, COSV53649823; called by muse, mutect2, varscan2
- SST | c.37C>T p.L13= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV55030360; called by muse, mutect2, varscan2
- STPG3 | c.744G>A p.S248= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs747539546, COSV58023691; called by muse, mutect2, varscan2
- SUSD2 | c.1410G>A p.E470= | Silent (SNP) | VAF 48/200 reads (24%) | catalogued as COSV64202798; called by muse, mutect2, varscan2
- TMEM43 | c.990C>T p.L330= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as rs780129544, COSV60145284; called by muse, mutect2, varscan2
- TONSL | c.3159C>T p.A1053= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV68047641; called by muse, mutect2, varscan2
- VCAN | c.6207G>A p.T2069= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs563628544, COSV54097241; called by muse, mutect2, varscan2
- ZFHX4 | c.48G>A p.Q16= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as rs1247297483, COSV50502032; called by muse, mutect2, varscan2
- ZNF629 | c.1986C>T p.Y662= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV52697451; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048789 T>C | 5'Flank (SNP) | VAF 310/804 reads (39%) | catalogued as rs759806033; called by muse, mutect2, varscan2
- EFNA5 | c.-33_-1del | 5'UTR (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel
- HERC2P3 | chr15:20457948 A>T | 5'Flank (SNP) | VAF 24/186 reads (13%) | catalogued as rs1230832598; called by muse, varscan2
- UCHL5 | chr1:193059770 G>A | 5'Flank (SNP) | VAF 245/348 reads (70%) | catalogued as COSV100814689; called by muse, varscan2
